Somatic mutation profile of tumor specimen TCGA-ER-A19Q-06A (aliquot TCGA-ER-A19Q-06A-11D-A197-08) from TCGA case TCGA-ER-A19Q, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 40.8 years (14,905 days).
Specimen TCGA-ER-A19Q-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 085aa1f0-7e90-45aa-8be9-516ee4788454.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19Q-10A (Blood Derived Normal), aliquot TCGA-ER-A19Q-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bf9c6b2-3419-4e8a-a6d7-451cdef1bf55

The open-access MAF lists 145 somatic variants for this specimen: 102 protein-altering or splice-affecting, 42 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 42, Nonsense Mutation 6, Splice Region 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.4135C>T p.R1379C | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852673, CM067626, CM152361, COSV56856915; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- INSR | c.3059G>A p.R1020Q | Missense Mutation (SNP) | VAF 79/152 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs121913148, CM910241, COSV57172361; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRL1 | c.3452G>A p.R1151K (on ENST00000340736 / NM_001008701.3; = p.R1146K on NM_014921.5) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61566480; called by muse, mutect2, varscan2
- ADH6 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756863693, COSV52955529; called by muse, mutect2, varscan2
- AGTRAP | c.63G>A p.W21* | Nonsense Mutation (SNP) | VAF 37/111 reads (33%) | catalogued as COSV58668800, COSV58669441; called by muse, mutect2, varscan2
- ALCAM | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 25/93 reads (27%) | catalogued as rs1448199395, COSV60250831; called by muse, mutect2, varscan2
- AZGP1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs772831043, COSV52797649; called by muse, mutect2, varscan2
- BCL7A | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV55846694, COSV55847490; called by muse, mutect2, varscan2
- CACNA1E | c.2651T>C p.L884P | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100704163; called by muse, mutect2, varscan2
- CCDC158 | c.2912C>T p.S971L | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV66357071; called by muse, mutect2, varscan2
- CD163L1 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.469); catalogued as COSV58020915; called by muse, mutect2, varscan2
- CHI3L1 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); catalogued as rs1435644487, COSV55139965; called by muse, varscan2
- CHI3L1 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.962); catalogued as COSV55140015; called by muse, varscan2
- CHI3L2 | c.*2G>A | Splice Region (SNP) | VAF 24/58 reads (41%) | catalogued as rs1468778812, COSV63874825; called by muse, mutect2, varscan2
- CNTN6 | c.123A>T p.L41F | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV63188010; called by muse, mutect2, varscan2
- CNTNAP5 | c.2353G>A p.G785S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV70509766; called by muse, mutect2, varscan2
- COL11A1 | c.2539G>A p.G847R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62195740; called by muse, mutect2, varscan2
- CSMD2 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1375628081, COSV53957195; called by muse, mutect2, varscan2
- DAP3 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 8/96 reads (8%) | catalogued as COSV58022632; called by muse, mutect2
- DCAF8L1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.291); catalogued as COSV71595505; called by muse, mutect2, varscan2
- DCAKD | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777222686, COSV60201883; called by muse, mutect2, varscan2
- DCLRE1B | c.1474C>T p.L492F | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV65813590; called by muse, mutect2, varscan2
- DNAH10 | c.2291G>A p.R764K (on ENST00000409039; = p.R703K on NM_207437.3) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV69000427; called by muse, mutect2, varscan2
- DNAH11 | c.9394C>T p.H3132Y | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV60974937; called by muse, mutect2, varscan2
- DNAH6 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV52880988; called by mutect2, varscan2
- DNAH7 | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV56762530; called by muse, mutect2, varscan2
- DOCK11 | c.2200C>T p.H734Y | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52245906; called by muse, mutect2, varscan2
- EBF1 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58168973, COSV58177101; called by mutect2, varscan2
- ENAM | c.2399C>T p.P800L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as rs1274649806, COSV68536873; called by muse, mutect2, varscan2
- FAM53C | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV53512846; called by muse, mutect2, varscan2
- FOS | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57840341; called by muse, mutect2, varscan2
- GABBR2 | c.1727G>A p.W576* | Nonsense Mutation (SNP) | VAF 10/19 reads (53%) | catalogued as COSV52317812; called by muse, mutect2, varscan2
- GIMAP5 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs866287630, COSV57530443; called by muse, mutect2, varscan2
- GLI1 | c.2323C>T p.P775S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.327); catalogued as COSV99954391; called by muse, mutect2, varscan2
- GUCY2C | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as rs376869445, COSV53795028; called by mutect2, varscan2
- IGF1R | c.3758C>T p.P1253L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51369359; called by muse, mutect2, varscan2
- ITGB5 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99950921; called by muse, mutect2
- KCND3 | c.1727T>C p.I576T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.334); catalogued as COSV56188782; called by muse, mutect2, varscan2
- KCNV2 | c.593G>A p.C198Y | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767845584, COSV66057448; called by mutect2, varscan2
- KIF20B | c.5047C>T p.P1683S (on ENST00000371728 / NM_001284259.2; = p.P1643S on NM_016195.4) | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as COSV53314778; called by muse, mutect2, varscan2
- LCE1B | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV63980463; called by muse, mutect2, varscan2
- LHFPL5 | c.580T>A p.F194I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV64178684; called by mutect2, varscan2
- LPO | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1206669463, COSV51862198; called by muse, mutect2, varscan2
- LRRFIP2 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs755790462, COSV60870049; called by muse, mutect2, varscan2
- LUM | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs267603717, COSV57127483, COSV57127798; called by muse, mutect2, varscan2
- MAP7D1 | c.2501C>T p.S834F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV60218357; called by muse, mutect2, varscan2
- MFSD8 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as COSV56552912; called by muse, mutect2, varscan2
- MYH4 | c.4408G>A p.E1470K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV55117995; called by muse, mutect2, varscan2
- MYH4 | c.2525C>T p.P842L | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV55125365; called by muse, mutect2, varscan2
- MYNN | c.760G>T p.V254F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.954); catalogued as COSV62992272; called by muse, varscan2
- NBEAL1 | c.7006C>T p.R2336C | Missense Mutation (SNP) | VAF 142/439 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs267599166, COSV68917177; called by muse, mutect2, varscan2
- NCAN | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV53057796; called by muse, mutect2, varscan2
- NDRG4 | c.813G>A p.Q271= (on ENST00000570248 / NM_001378344.1; = p.Q303= on NM_020465.4 and 5 other RefSeq transcripts) | Splice Region (SNP) | VAF 19/62 reads (31%) | catalogued as COSV50751301; called by muse, mutect2, varscan2
- NID2 | c.3373G>A p.G1125S | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV53502214; called by muse, mutect2, varscan2
- NRXN1 | c.3229G>A p.E1077K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs1460279109, COSV100456117, COSV58462940, COSV58477259; called by muse, mutect2, varscan2
- NRXN2 | c.1709G>A p.G570E | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55448174; called by muse, mutect2, varscan2
- NSA2 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV99713761; called by muse, mutect2, varscan2
- NSA2 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV99713764; called by muse, mutect2, varscan2
- NXF1 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53672939, COSV53676395; called by muse, mutect2, varscan2
- OPRPN | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as rs952969590, COSV68193528; called by muse, mutect2, varscan2
- OR14J1 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV65845961; called by muse, mutect2, varscan2
- OR4C16 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as rs762366474, COSV58944121; called by muse, mutect2, varscan2
- OR9A4 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs267601322, COSV71885648, COSV71886018; called by muse, mutect2, varscan2
- ORAI2 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.04); catalogued as rs751764863, COSV62690394; called by muse, mutect2, varscan2
- PCDHB5 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554275808, COSV50668209; called by muse, mutect2, varscan2
- PCF11 | c.2771C>G p.S924* | Nonsense Mutation (SNP) | VAF 35/55 reads (64%) | catalogued as COSV53537141; called by muse, mutect2, varscan2
- PERP | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV101408599; called by muse, mutect2, varscan2
- PGAP1 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61329292; called by muse, mutect2, varscan2
- PPARGC1B | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs566916898, COSV58532776; called by mutect2, varscan2
- PPP1CB | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); catalogued as COSV56091836; called by muse, mutect2, varscan2
- PRPF40A | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58444131; called by muse, mutect2, varscan2
- RFX7 | c.1376C>T p.S459F (on ENST00000559447 / NM_001368074.1; = p.S556F on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV57968359; called by muse, mutect2, varscan2
- RNF17 | c.791G>C p.R264P | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.615); catalogued as COSV55042705, COSV55050126; called by muse, mutect2, varscan2
- RNF31 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); catalogued as rs1310867659, COSV53761119; called by muse, mutect2, varscan2
- SERPINI2 | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV52986179; called by muse, mutect2, varscan2
- SEZ6L | c.2581C>T p.R861C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs779505302, COSV50659958; called by muse, mutect2, varscan2
- SLC15A2 | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs267599570, COSV55200665; called by muse, mutect2, varscan2
- SLC22A8 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60326922; called by muse, mutect2, varscan2
- SLC26A1 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749562383, COSV56106148; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLK | c.3109C>T p.Q1037* | Nonsense Mutation (SNP) | VAF 41/103 reads (40%) | catalogued as rs1274900601, COSV59825058; called by muse, mutect2, varscan2
- SMAD4 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61694027; called by muse, mutect2, varscan2
- SMU1 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV68140306; called by muse, mutect2, varscan2
- SP140 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV59454538; called by muse, mutect2, varscan2
- SRP19 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51583207; called by muse, mutect2, varscan2
- STON1 | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59137481; called by muse, mutect2, varscan2
- TLL2 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV63571763; called by muse, mutect2, varscan2
- TMEM201 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.338); catalogued as COSV100440536; called by muse, mutect2, varscan2
- TMEM63C | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV53608283; called by muse, mutect2, varscan2
- TOGARAM2 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.089); catalogued as rs767132742, COSV65423679; called by muse, mutect2, varscan2
- TRIOBP | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs758476559, COSV60373429; called by muse, mutect2, varscan2
- TRPM3 | c.4327G>A p.A1443T (on ENST00000357533 / NM_001366142.2; = p.A1298T on NM_020952.6) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV62583820, COSV62593891; called by muse, varscan2
- TTN | c.39772G>A p.E13258K (on ENST00000591111; = p.E5834K on NM_003319.4) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | PolyPhen benign (0.154); catalogued as rs868648105, COSV59934309; called by muse, mutect2, varscan2
- UBASH3A | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.267); catalogued as rs1163879889, COSV52311087; called by muse, mutect2, varscan2
- UGT3A2 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV99236653; called by mutect2, varscan2
- UNC13C | c.4885G>A p.E1629K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs200137468, COSV52872827; called by muse, mutect2, varscan2
- USP6 | c.4198G>A p.E1400K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs755591470, COSV51495244; called by muse, mutect2, varscan2
- VSIG10 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.983); catalogued as COSV63654366; called by muse, mutect2, varscan2
- XPNPEP3 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64028307; called by muse, mutect2, varscan2
- ZC3H7B | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV60964417; called by muse, mutect2, varscan2
- ZNF521 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.028); catalogued as rs774461694, COSV64131400; called by muse, mutect2, varscan2
- PRAMEF15 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 57/243 reads (23%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); called by muse, varscan2
- ADAMTS7 | c.3174G>C p.V1058= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV66309266; called by muse, mutect2, varscan2
- AMZ1 | c.129C>T p.F43= | Silent (SNP) | VAF 45/198 reads (23%) | catalogued as COSV100406161, COSV56688952; called by muse, mutect2, varscan2
- ARHGAP44 | c.591C>T p.L197= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV52401722; called by muse, mutect2, varscan2
- C1orf87 | c.90C>T p.L30= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs1022530029, COSV100967187; called by muse, mutect2, varscan2
- CACNA1E | c.2650C>T p.L884= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV100704158; called by muse, mutect2, varscan2
- CFAP65 | c.708G>A p.R236= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV99838396; called by muse, mutect2, varscan2
- CHD5 | c.2919C>T p.S973= | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as COSV52423906; called by muse, mutect2, varscan2
- CHIA | c.150C>T p.L50= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV58477857; called by muse, mutect2, varscan2
- FAM13A | c.2058C>T p.F686= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs1198606677, COSV52000394, COSV99983575; called by muse, mutect2, varscan2
- FLNA | c.1038C>T p.Y346= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs1057522072, COSV61050657; ClinVar: likely benign; called by mutect2, varscan2
- FOLR1 | c.705G>A p.G235= | Silent (SNP) | VAF 68/107 reads (64%) | catalogued as COSV56617115; called by muse, mutect2, varscan2
- HINT2 | c.207C>T p.L69= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV52414067, COSV52415647; called by muse, mutect2, varscan2
- HSPA1A | c.1866C>T p.F622= | Silent (SNP) | VAF 217/414 reads (52%) | catalogued as rs746592204, COSV65149465; called by muse, mutect2, varscan2
- INTS1 | c.2970C>T p.A990= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV67179538; called by muse, mutect2, varscan2
- ITGA11 | c.1731C>T p.F577= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV59881597; called by mutect2, varscan2
- ITGA6 | c.1938G>A p.L646= (on ENST00000442250; = p.L607= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV51232387; called by muse, mutect2, varscan2
- MGAM | c.3927G>A p.G1309= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV72075721; called by muse, mutect2, varscan2
- MKI67 | c.4036C>T p.L1346= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV64076600; called by muse, mutect2, varscan2
- MTFMT | c.960A>G p.L320= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs1347467934, COSV54979649; called by muse, mutect2, varscan2
- NEXMIF | c.594G>A p.Q198= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV50094245; called by muse, mutect2, varscan2
- NT5C3B | c.81C>T p.A27= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs782020992, COSV53174655; called by muse, mutect2
- OR1G1 | c.496C>T p.L166= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs1203814797, COSV61030165; called by muse, mutect2, varscan2
- OR2A2 | c.807G>A p.Q269= | Silent (SNP) | VAF 73/175 reads (42%) | catalogued as COSV68872472; called by muse, mutect2, varscan2
- OR4D1 | c.273G>A p.T91= | Silent (SNP) | VAF 55/124 reads (44%) | catalogued as rs17222013, COSV52124886; called by muse, mutect2, varscan2
- OR4K5 | c.897G>A p.R299= | Silent (SNP) | VAF 25/174 reads (14%) | catalogued as rs749816085, COSV60003526; called by muse, mutect2, varscan2
- OR5D14 | c.144C>T p.I48= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV59457635, COSV59458328; called by muse, mutect2, varscan2
- PRSS1 | c.18C>T p.I6= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV61190804; called by muse, mutect2, varscan2
- PTH1R | c.1245C>T p.P415= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV57317625; called by muse, mutect2
- PTPRT | c.2388G>A p.R796= | Silent (SNP) | VAF 102/184 reads (55%) | catalogued as rs1448838211, COSV61980285; called by muse, mutect2, varscan2
- RFX7 | c.786C>T p.I262= (on ENST00000559447 / NM_001368074.1; = p.I359= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs373795444, COSV57968374; called by muse, mutect2, varscan2
- SALL3 | c.2652C>T p.G884= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs187638087, COSV73305930; called by muse, mutect2, varscan2
- SIM2 | c.861G>A p.K287= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV51772567; called by muse, mutect2, varscan2
- SSH3 | c.1347C>T p.I449= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as rs770023721, COSV57386587; called by mutect2, varscan2
- SUSD6 | c.363A>T p.I121= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV61366669; called by muse, mutect2, varscan2
- TBRG4 | c.198C>T p.P66= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV51834345; called by muse, mutect2, varscan2
- TFE3 | c.1555C>T p.L519= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV100252697; called by muse, mutect2, varscan2
- TFE3 | c.1554C>T p.H518= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV100252699; called by muse, mutect2, varscan2
- TMEM201 | c.318C>T p.D106= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs772202797, COSV100440534; called by muse, mutect2, varscan2
- TP63 | c.387G>A p.S129= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs151335217; called by mutect2, varscan2
- UBR2 | c.4926C>T p.S1642= | Silent (SNP) | VAF 65/119 reads (55%) | catalogued as COSV100867483; called by muse, mutect2, varscan2
- ZFP42 | c.825C>T p.F275= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as rs1242846950, COSV104400648, COSV58816992; called by muse, mutect2, varscan2
- ZNF615 | c.1731A>G p.L577= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV65034823; called by muse, mutect2, varscan2
- MACF1 | c.15832-10321A>C | Intron (SNP) | VAF 22/71 reads (31%) | catalogued as COSV57141735; called by muse, mutect2, varscan2
